Gene-level copy-number profile of tumor specimen CUPP-B4JB-TTM1-A from CCG case CUPP-B4JB, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.2 years (21,252 days).
Specimen CUPP-B4JB-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d538acb2-ab7c-4943-a7b0-8d277feceaac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B4JB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,261 have no estimate.
https://portal.gdc.cancer.gov/files/f535df77-2fe4-4fa1-9a2f-5327a6daf75f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 1,772; copy number 3: 21,275; copy number 4: 21,781; copy number 5: 2,668; copy number 6: 5,791; copy number 7: 3,929; copy number 8: 148; copy number 9: 96; copy number 10: 134; copy number 11: 1; copy number 13: 185; copy number 14: 184; copy number 15: 57; copy number 19: 3; copy number 21: 9; copy number 25: 14; copy number 26: 18; copy number 27: 59; copy number 28: 102; copy number 30: 2; copy number 38: 1; copy number 41: 11; copy number 44: 26; copy number 46: 2; copy number 60: 11; copy number 63: 7; copy number 69: 5; copy number 82: 5; copy number 90: 15; copy number 96: 37; copy number 175: 1; copy number 231: 7; copy number 261: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,070 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 7–10 (broad region; genes not listed).
- chr2:86,440,647–92,035,000, 169 genes, copy number 7–10 (broad region; genes not listed).
- chr2:160,849,313–222,946,388, 1,003 genes, copy number 7 (broad region; genes not listed).
- chr2:224,169,664–237,842,808, 244 genes, copy number 7–8 (broad region; genes not listed).
- chr2:238,788,648–242,175,634, 94 genes, copy number 7 (broad region; genes not listed).
- chr7:36,838,972–36,841,373, 1 gene, copy number 175: AC007349.2.
- chr7:50,095,883–55,433,742, 61 genes, copy number 11–231 (within-gene range 3–231) (broad region; genes not listed).
- chr7:55,592,074–56,955,864, 65 genes, copy number 13 (broad region; genes not listed).
- chr7:57,060,590–57,837,046, 54 genes, copy number 13: PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr8:145,047,860–145,066,685, 2 genes, copy number 8: AC139103.1, C8orf33.
- chr11:68,024,809–78,444,049, 336 genes, copy number 13–96 (within-gene range 3–96) (broad region; genes not listed).
- chr12:12,310–38,133, 3 genes, copy number 9: DDX11L8, WASH8P, FAM138D.
- chr12:24,212,421–34,249,958, 213 genes, copy number 13–261 (broad region; genes not listed).
- chr14:18,333,726–18,650,966, 17 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr20:31,257,664–33,443,763, 89 genes, copy number 7–9 (broad region; genes not listed).
- chr20:46,684,365–48,494,309, 39 genes, copy number 9 (within-gene range 3–9): TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P.
- chr20:50,247,643–50,585,879, 10 genes, copy number 9: PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645.
- chr20:51,596,514–51,862,912, 4 genes, copy number 9: ATP9A, AL138807.1, SALL4, LINC01429.
- chr20:52,972,358–53,875,557, 16 genes, copy number 9 (within-gene range 3–9): TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1.
- chr20:62,302,093–64,327,972, 126 genes, copy number 8–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
